Somatic mutation profile of tumor specimen TCGA-14-1825-01A (aliquot TCGA-14-1825-01A-01W-0643-08) from TCGA case TCGA-14-1825, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.3 years (25,684 days).
Specimen TCGA-14-1825-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e26ee25-6784-41de-a23f-3e598b17bd24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1825-10A (Blood Derived Normal), aliquot TCGA-14-1825-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92bcfa52-461e-4f8e-803f-bf914b5bfbd0

The open-access MAF lists 90 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 21, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 22/120 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 120/165 reads (73%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.905A>C p.H302P | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55540815; called by muse, mutect2, varscan2
- AARS1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55749833; called by muse, mutect2, varscan2
- CHRNB3 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51495439; called by muse, mutect2
- CYSLTR2 | c.658T>A p.C220S | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV56167142; called by muse, mutect2, varscan2
- DCAF12L1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421605; called by muse, mutect2, varscan2
- EXOC1 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.592); catalogued as COSV100637775; called by muse, mutect2, varscan2
- FBXO24 | c.402C>A p.H134Q (on ENST00000241071 / NM_033506.3; = p.H172Q on NM_012172.5) | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV53825075; called by muse, mutect2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 22/148 reads (15%) | catalogued as rs752538869; called by mutect2, varscan2
- GPR183 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs746590981; called by mutect2, varscan2
- GRIN2A | c.110C>A p.A37E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58045396; called by muse, mutect2, varscan2
- HFE | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV58514096; called by muse, mutect2, varscan2
- HPX | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 53/224 reads (24%) | catalogued as COSV56419846; called by muse, varscan2
- INSRR | c.3826G>A p.D1276N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs780044274, COSV63872656, COSV63876729; called by muse, mutect2, varscan2
- IRAG2 | c.3040C>A p.L1014I (on ENST00000636465; = p.L59I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV63137968; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 32/198 reads (16%) | catalogued as rs761558950; called by mutect2, varscan2
- KIF4B | c.3557C>A p.A1186D | Missense Mutation (SNP) | VAF 82/133 reads (62%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV70528446, COSV70531810; called by muse, mutect2, varscan2
- L1TD1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs778590430, COSV63133564; called by muse, mutect2, varscan2
- MADD | c.1479G>A p.M493I | Missense Mutation (SNP) | VAF 69/529 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs779048806; called by muse, mutect2, varscan2
- MAGEA10 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 77/82 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV54885674; called by muse, mutect2, varscan2
- MED22 | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 134/156 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1355030719, COSV59300329; called by muse, mutect2, varscan2
- MMP19 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.692); catalogued as COSV59453480; called by muse, mutect2, varscan2
- NFE2L3 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV50227181; called by muse, mutect2, varscan2
- NUAK1 | c.1047G>T p.M349I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54608256; called by muse, mutect2, varscan2
- OR52R1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 114/171 reads (67%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100617799, COSV61888998; called by muse, mutect2, varscan2
- PDGFRL | c.353+1G>A p.X118_splice | Splice Site (SNP) | VAF 39/111 reads (35%) | catalogued as rs1480843932, COSV52415570; called by muse, mutect2, varscan2
- PEX14 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); catalogued as COSV63060816, COSV63063915; called by muse, mutect2, varscan2
- PLIN2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52804536; called by muse, mutect2, varscan2
- PRKAB1 | c.80dup p.T28Hfs*39 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | catalogued as rs765766033; called by pindel, varscan2
- RANBP6 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52391762; called by muse, varscan2
- RASGRF2 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54130045; called by muse, mutect2
- RBAK | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 123/512 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1345120337, COSV62332626; called by muse, mutect2, varscan2
- RNF123 | c.3233C>T p.S1078L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs749212060, COSV57539215; called by muse, mutect2, varscan2
- SLC44A1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs780698255, COSV66027486; called by muse, mutect2, varscan2
- TBC1D32 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377465896; called by muse, mutect2, varscan2
- TEX29 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as COSV52097065; called by muse, varscan2
- THNSL1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV64480012; called by muse, mutect2, varscan2
- TIPARP | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 240/1303 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as rs766769030, COSV55815866; called by muse, mutect2, varscan2
- TRPC4AP | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs146813768; called by muse, mutect2, varscan2
- ABCC8 | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKMY1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, varscan2
- CEACAM6 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- FAM153A | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 21/306 reads (7%) | called by muse, mutect2, varscan2
- FZD2 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GPR151 | c.458C>G p.T153S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.223); called by mutect2, varscan2
- HPX | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2
- IGF2R | c.1701del p.D568Mfs*30 | Frame Shift Del (DEL) | VAF 60/125 reads (48%) | called by mutect2, pindel, varscan2
- INPP5E | c.1814C>A p.A605E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- IQSEC3 | c.1499C>A p.S500Y (on ENST00000538872 / NM_001170738.2; = p.S197Y on NM_015232.1) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KDM3B | c.1760G>T p.S587I | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LEO1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 314/1015 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- MACF1 | c.930+1G>T p.X310_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | called by muse, varscan2
- MTOR | c.5069C>T p.P1690L | Missense Mutation (SNP) | VAF 82/820 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10G3 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.926); called by muse, mutect2
- PAPOLA | c.1441A>G p.M481V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- PARP3 | c.1184T>A p.L395H | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PDSS1 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.374); called by muse, mutect2
- PRPF19 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- RASGRF1 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- RPGR | c.2657A>G p.E886G (on ENST00000339363 / NM_001367249.1; = p.E681G on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- SATB1 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA18 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SPTBN1 | c.5623G>A p.A1875T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM132A | c.2692C>A p.L898M (on ENST00000453848 / NM_178031.3; = p.L899M on NM_017870.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TP53BP1 | c.5192G>T p.G1731V | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF345 | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); called by muse, mutect2
- ACP3 | c.222C>T p.G74= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- CABS1 | c.525C>T p.D175= | Silent (SNP) | VAF 65/109 reads (60%) | catalogued as rs541997419, COSV56734707; called by muse, mutect2, varscan2
- CDHR2 | c.2892C>T p.I964= | Silent (SNP) | VAF 19/70 reads (27%) | called by muse, varscan2
- CDHR2 | c.2967C>T p.I989= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, varscan2
- CLEC10A | c.258G>A p.E86= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- CLP1 | c.147G>T p.L49= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- COL8A1 | c.618C>A p.G206= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ENDOU | c.741C>T p.L247= (on ENST00000422538 / NM_001172439.2; = p.L206= on NM_006025.4) | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- ITIH6 | c.3396G>A p.P1132= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as rs917219668, COSV54495308; called by muse, mutect2, varscan2
- MAST2 | c.1407C>T p.T469= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1221027260; called by muse, varscan2
- MBTPS2 | c.114G>T p.L38= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- MC3R | c.519C>T p.G173= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as COSV54765103; called by muse, mutect2, varscan2
- MYF6 | c.69G>A p.Q23= | Silent (SNP) | VAF 78/106 reads (74%) | catalogued as COSV57353577; called by muse, mutect2, varscan2
- OR2J2 | c.249G>T p.L83= | Silent (SNP) | VAF 34/717 reads (5%) | called by muse, mutect2
- PDE1C | c.1290C>T p.F430= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV58503751; called by muse, mutect2
- PPM1D | c.759C>T p.H253= | Silent (SNP) | VAF 88/112 reads (79%) | catalogued as rs749755269, COSV59958303; called by muse, mutect2, varscan2
- RHBDL3 | c.1179C>T p.Y393= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- TAL1 | c.624C>T p.A208= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as rs780848420, COSV53748403; called by muse, mutect2, varscan2
- TSHZ2 | c.237C>T p.A79= | Silent (SNP) | VAF 36/415 reads (9%) | catalogued as rs781424430, COSV61587878; called by muse, mutect2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- ZHX3 | c.1188C>A p.V396= | Silent (SNP) | VAF 52/678 reads (8%) | called by muse, mutect2
- ANKRD20A5P | n.272G>T | RNA (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- KRTAP6-2 | c.-1G>A | 5'UTR (SNP) | VAF 130/225 reads (58%) | catalogued as rs1302409762, COSV58182247; called by muse, mutect2, varscan2
